Somatic mutation profile of tumor specimen TCGA-A5-A0G2-01A (aliquot TCGA-A5-A0G2-01A-11W-A062-09) from TCGA case TCGA-A5-A0G2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.4 years (20,953 days).
Specimen TCGA-A5-A0G2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 947f0dc0-02ee-46ff-9b00-32935d951df0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0G2-10A (Blood Derived Normal), aliquot TCGA-A5-A0G2-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/411a606d-f354-4561-b42c-eb1bc155c87d

The open-access MAF lists 31,298 somatic variants for this specimen: 23,124 protein-altering or splice-affecting, 7,560 silent, 614 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20,646, Silent 7,560, Nonsense Mutation 1,652, Splice Site 464, Intron 251, Splice Region 213, RNA 157, Frame Shift Ins 94, 3'UTR 76, 3'Flank 44, 5'Flank 43, 5'UTR 43.

Variants (750 of 31,298; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480620711; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA4 | c.4577C>T p.T1526M | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs61750152, CM990057; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61750065, CM990038, COSV64672644; ClinVar: likely pathogenic; called by muse, varscan2
- ABCD1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1557054776, CD107886, CM000642, COSV99497521; ClinVar: pathogenic; called by muse, mutect2
- ACTG2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs78001248, CM143764, COSV100609536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121908469, CM012887, COSV63020562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, varscan2
- APC | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 39/154 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.26); PolyPhen benign (0.29); catalogued as rs373428732; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 58/209 reads (28%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.3136G>A p.G1046R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.999); catalogued as rs376997378, CM1512236, COSV52465311; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as rs138941496, CM960105, COSV53725297, COSV99588934; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553245771, CM111486, COSV100767794; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776280797, CM980192; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ATP7B | c.2071G>A p.G691R | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908001, CM980170; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAX | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs398122513, COSV53170407; ClinVar: pathogenic; called by muse, varscan2
- BBS2 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 51/265 reads (19%) | catalogued as rs764164384, CM016220; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS9 | c.263+1G>A p.X88_splice | Splice Site (SNP) | VAF 34/171 reads (20%) | catalogued as rs137962929, CS1414372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTD | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs367902696, CM105601; ClinVar: likely pathogenic; called by muse, varscan2
- BTD | c.399G>A p.E133= | Splice Region (SNP) | VAF 10/44 reads (23%) | catalogued as rs397514360, CS993585; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- BTD | c.1400G>A p.W467* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as rs1277029090; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908212, CM960238, COSV64189612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1S | c.3716G>A p.R1239H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs28930068, CM950188, COSV100755215, COSV62939543; ClinVar: pathogenic; called by mutect2, varscan2
- CASK | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1114167352, COSV59364220; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- CFTR | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as rs79850223, CM920180, COSV50107726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD3 | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1567863732, COSV100390718; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | catalogued as rs587779463, CS116428; ClinVar: pathogenic; called by mutect2, varscan2
- COL3A1 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779539, CM0910090, CM1412539; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559872489; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs371334239, CM014040, COSV67417567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.3210+1G>A p.X1070_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as rs1553762314, CS1312547, COSV59258120; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.9058C>T p.R3020* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | catalogued as rs374144275; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNND1 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780642639; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP17A1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs61754278, CM960476, COSV64004824; ClinVar: pathogenic; called by muse, varscan2
- DEAF1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751569402; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- DGKE | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 42/92 reads (46%) | catalogued as rs762576212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 103/250 reads (41%) | catalogued as rs754818927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs398123865, CM080213; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs755995375, COSV61576496; called by muse, mutect2, varscan2
- DOCK7 | c.5101C>T p.R1701* (on ENST00000635253 / NM_001367561.1; = p.R1670* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as rs1419019482, COSV52004038; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DPYD | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 44/196 reads (22%) | catalogued as rs1057516968, CM161357, COSV64613429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF2AK4 | c.2458C>T p.R820* | Nonsense Mutation (SNP) | VAF 55/135 reads (41%) | catalogued as rs774163084, CM140025; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF2AK4 | c.3406C>T p.R1136* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs587777105, CM140017, COSV55470712; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB4 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs267599192, COSV53516478; ClinVar: likely pathogenic; called by muse, varscan2
- ETV6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159945, CM150817, COSV56766387, COSV56766702, COSV56766787; ClinVar: pathogenic; called by muse, varscan2
- FBN1 | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763449629, CM040037, CM043996, COSV57328127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121918508, CM060995, COSV60650006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNA | c.1923C>T p.G641= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs80338841, CS062053, COSV61040235; ClinVar: pathogenic; called by muse, mutect2
- GAA | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121907937, CM082740, CM910166, COSV56408643; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- GALC | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749893889, CM970566, COSV99730818; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GALC | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 46/208 reads (22%) | catalogued as rs771111145, CM108555; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCM2 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs104893960, CM051509; ClinVar: pathogenic; called by muse, varscan2
- GLB1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780724173, CM064028, COSV56566122; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- GNAS | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1131691999, CM013729, CM013730, COSV55691267; ClinVar: likely pathogenic; called by muse, varscan2
- GNB5 | c.1120C>T p.R374* (on ENST00000261837 / NM_016194.4; = p.R332* on NM_006578.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as rs773902879, COSV55899984; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPAT | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442079596, COSV64153814; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as rs786204585, CM113520, COSV51507538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HGSNAT | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756310864, CM065264; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF4A | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1085307913, CM082880; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HOGA1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs796052086, CM118808; ClinVar: pathogenic; called by muse, mutect2
- HRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs727503093, COSV54244375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IQCB1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 91/399 reads (23%) | catalogued as rs1189889920, CM050645, COSV60437893; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGA2B | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766503255, CM113241, COSV52231603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IYD | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs121918140, CM086838; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH1 | c.1070G>A p.R357Q (on ENST00000271751 / NM_172362.3; = p.R330Q on NM_002238.4) | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs886041300, CM1511903, CM165939, COSV99659211; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNJ1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs104894253, CM108760, CM970812, COSV60661395, COSV60662134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 245/590 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1554829003, COSV99695945; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KIT | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 34/121 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs776681643, COSV55391670, COSV99855011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2B | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568377293, COSV55858441; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 52/99 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs1563313372, CM022615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- LDLR | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs764042910, CM1010085; ClinVar: pathogenic; called by mutect2, varscan2
- LRP4 | c.547+1G>A p.X183_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as rs762425885, CS102959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRP4 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs267607222, CM102952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LYST | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 76/210 reads (36%) | catalogued as rs1558282769, CM132323; ClinVar: likely pathogenic; called by muse, varscan2
- MED23 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766478634, COSV51580995; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MKS1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs779953982; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as rs63750097, CM950812; ClinVar: pathogenic; called by muse, varscan2
- MSH6 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 167/306 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779617676, CM144063, COSV52274821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs727503258, COSV100805719; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.9061C>T p.R3021* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs1567658710; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NARS2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367584549, COSV55250404; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1555610884; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as rs1555614207, COSV100645763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5509G>A p.D1837N (on ENST00000358273 / NM_001042492.3; = p.D1816N on NM_000267.3) | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs771597781, COSV62199252; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 55/300 reads (18%) | catalogued as rs528583612, CM146810, COSV54983506; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530318579, CD077427, CM042095, COSV62635119; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NSDHL | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 77/105 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs104894909, CM001397, COSV64744774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1159+1G>A p.X387_splice | Splice Site (SNP) | VAF 71/269 reads (26%) | catalogued as rs1057520515; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX12 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 55/238 reads (23%) | catalogued as rs61752103, CM981517, COSV56777816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHEX | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 83/121 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs886041363, CM971163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 80/340 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRPH2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs61755787, CM951117, COSV57837952; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- PSMD12 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 64/172 reads (37%) | catalogued as rs895130488, COSV62066198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 125/285 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 114/298 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTH1R | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | catalogued as rs121434604, CM071063; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs28933392, CM961215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RDH5 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs375135224, CM109548; ClinVar: pathogenic; called by muse, varscan2
- REN | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as rs121917741, CM053391, COSV99689653; ClinVar: pathogenic; called by mutect2, varscan2
- RXYLT1 | c.743+1G>A p.X248_splice | Splice Site (SNP) | VAF 25/207 reads (12%) | catalogued as rs778174763, COSV54170124, COSV54170575; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs118192160, CM061939, CM140861, COSV62087706, COSV62099686; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.14582G>A p.R4861H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs63749869, CM013431; ClinVar: drug response / pathogenic; called by mutect2, varscan2
- RYR2 | c.12298G>A p.V4100I | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758785338, COSV63665946; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 35/185 reads (19%) | catalogued as rs1413469900, COSV56302192; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.5734C>T p.R1912* (on ENST00000303395 / NM_001202435.3; = p.R1901* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/244 reads (17%) | catalogued as rs77216276, CD114895, CM044053, COSV57661348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.3733C>T p.R1245* (on ENST00000303395 / NM_001202435.3; = p.R1234* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs727504136, CM031739, COSV57685915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.3434C>T p.T1145M | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs796053128, COSV51852982; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs121917753, CM040797, COSV51836018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4885C>T p.R1629* (on ENST00000333535 / NM_198056.3; = p.R1628* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 32/160 reads (20%) | catalogued as rs199473284, CM099835, CM100747; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.41); catalogued as rs761117662, COSV61118422; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as rs1057518900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC23B | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as rs121918225, CM094619; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SERAC1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 46/151 reads (30%) | catalogued as rs387907236, CM125509, COSV100894824, COSV100894917; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A11 | c.708C>T p.A236= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1567650874, COSV99337291; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC45A2 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912621, CM040825, COSV99672894; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | hotspot (GDC flag); catalogued as COSV50993252; called by muse, mutect2, varscan2
- SMCHD1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs886042392; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- SMPD1 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as rs120074127, CM951177; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG7 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as rs764791523, CM164818; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SUZ12 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | hotspot (GDC flag); catalogued as rs2627175; called by muse, mutect2, varscan2
- SYNGAP1 | c.3494C>T p.S1165L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs875989808; ClinVar: likely pathogenic; called by muse, mutect2
- TERT | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs149566858, CM066607, COSV57235537, COSV99720192; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.100831C>T p.R33611* (on ENST00000591111; = p.R26187* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/240 reads (18%) | catalogued as rs886043924, COSV60199217; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.89893C>T p.R29965* (on ENST00000591111; = p.R22541* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as rs1060500435, COSV100604948; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.57799C>T p.R19267* (on ENST00000591111; = p.R11843* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/95 reads (36%) | catalogued as rs543860009; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- USH2A | c.7595-1G>T p.X2532_splice | Splice Site (SNP) | VAF 57/151 reads (38%) | catalogued as rs1553273421; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.760G>A p.A254T (on ENST00000376372 / NM_001029896.2; = p.A255T on NM_007075.3) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1557083979; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 89/184 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, varscan2
- A2M | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs751226734; called by muse, mutect2
- A2M | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs956288566; called by muse, mutect2, varscan2
- A2ML1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs772972879; ClinVar: uncertain significance; called by muse, varscan2
- A2ML1 | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1277216051; called by muse, varscan2
- A2ML1 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.93); catalogued as rs375671514, COSV55297373; ClinVar: uncertain significance; called by muse, varscan2
- A4GALT | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs550617900; called by muse, varscan2
- AACS | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1259992246, COSV55537442; called by muse, mutect2, varscan2
- AADAC | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1263810165; called by muse, varscan2
- AADACL2 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866713481; called by muse, mutect2, varscan2
- AADACL3 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV100206744, COSV60198421; called by muse, mutect2, varscan2
- AADACL4 | c.169-1G>A p.X57_splice | Splice Site (SNP) | VAF 40/75 reads (53%) | catalogued as COSV100879509; called by muse, varscan2
- AADACL4 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs770760559, COSV66106769; called by muse, varscan2
- AAMDC | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1176418635; called by muse, mutect2
- AAR2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777915080; called by muse, mutect2, varscan2
- AAR2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs747683964, COSV100299444; called by muse, varscan2
- AARS1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.479); catalogued as COSV55746804; called by muse, mutect2, varscan2
- AARS2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs1257340539; called by muse, mutect2, varscan2
- AARS2 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55116363; called by muse, mutect2, varscan2
- AARS2 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as rs771082902, COSV99771395; called by muse, mutect2, varscan2
- AASDH | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1217671487, COSV52711119; called by muse, varscan2
- AASS | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1270495905; called by muse, mutect2, varscan2
- ABCA1 | c.6431G>A p.R2144Q | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs566760790; called by muse, mutect2, varscan2
- ABCA1 | c.4465-1G>T p.X1489_splice | Splice Site (SNP) | VAF 28/149 reads (19%) | catalogued as CS090177; called by muse, mutect2, varscan2
- ABCA1 | c.2170G>A p.V724M | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs138271089; called by muse, mutect2, varscan2
- ABCA1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66065648; called by mutect2, varscan2
- ABCA1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs138438101, COSV66057789; called by muse, varscan2
- ABCA10 | c.3879G>A p.W1293* | Nonsense Mutation (SNP) | VAF 51/229 reads (22%) | catalogued as rs775793828, COSV52230517; called by muse, mutect2, varscan2
- ABCA12 | c.5956G>A p.D1986N (on ENST00000272895 / NM_173076.3; = p.D1668N on NM_015657.3) | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.301); catalogued as rs746547558, COSV55949831; called by muse, mutect2, varscan2
- ABCA12 | c.4543C>T p.R1515* (on ENST00000272895 / NM_173076.3; = p.R1197* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as rs748413124, CM110697; called by muse, mutect2, varscan2
- ABCA12 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs753119888, COSV55959745; called by muse, mutect2, varscan2
- ABCA12 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 83/104 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs113648834, COSV99792281; called by muse, mutect2, varscan2
- ABCA13 | c.4528G>T p.D1510Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs373401108; called by muse, mutect2, varscan2
- ABCA13 | c.6065T>C p.L2022P | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs1374125976; called by muse, mutect2, varscan2
- ABCA13 | c.6307C>T p.H2103Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.215); catalogued as rs1487003634; called by muse, mutect2, varscan2
- ABCA13 | c.7009T>C p.Y2337H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.21); catalogued as rs550782793; called by muse, mutect2, varscan2
- ABCA13 | c.9583G>A p.A3195T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1165111589, COSV71289751; called by mutect2, varscan2
- ABCA13 | c.10413G>T p.K3471N | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV71289737, COSV71291474; called by muse, mutect2, varscan2
- ABCA13 | c.12547G>A p.G4183R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV71286010; called by muse, mutect2, varscan2
- ABCA13 | c.12826G>A p.D4276N | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs765749513, COSV68943080; called by muse, mutect2, varscan2
- ABCA13 | c.14943G>T p.K4981N | Missense Mutation (SNP) | VAF 59/369 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777337643; called by muse, mutect2, varscan2
- ABCA3 | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs768088208; called by muse, mutect2, varscan2
- ABCA4 | c.2147C>T p.T716M | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as rs61749426, CM015074; ClinVar: not provided; called by muse, mutect2, varscan2
- ABCA5 | c.4208G>A p.G1403E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101201104; called by muse, mutect2, varscan2
- ABCA6 | c.3283G>A p.V1095M | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as rs756151634, COSV99447836; called by muse, varscan2
- ABCA6 | c.2741-1G>T p.X914_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | catalogued as rs1048795483; called by muse, mutect2, varscan2
- ABCA6 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV52645812; called by muse, mutect2, varscan2
- ABCA8 | c.2512C>A p.L838I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV52197902; called by muse, mutect2, varscan2
- ABCA8 | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as rs368751441; called by muse, mutect2, varscan2
- ABCA9 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs764563080, COSV100382512, COSV60631257; called by mutect2, varscan2
- ABCA9 | c.2055G>T p.R685S | Missense Mutation (SNP) | VAF 152/362 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60627417; called by muse, varscan2
- ABCB10 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as rs373845536; called by mutect2, varscan2
- ABCB11 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV55598957; called by muse, mutect2, varscan2
- ABCB4 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55935210; called by muse, mutect2, varscan2
- ABCB5 | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1043550322; called by muse, varscan2
- ABCB6 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs780297861; called by mutect2, varscan2
- ABCB8 | c.823C>T p.R275* (on ENST00000297504 / NM_001282291.2; = p.R258* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs369818772; called by muse, mutect2, varscan2
- ABCB9 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287075211, COSV54894413; called by muse, mutect2, varscan2
- ABCC1 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs768011444, COSV60695411; called by muse, mutect2, varscan2
- ABCC1 | c.2911G>A p.G971R | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1198050880, COSV60693454; called by muse, mutect2, varscan2
- ABCC1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs942306533, COSV60695342; called by muse, mutect2, varscan2
- ABCC1 | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1019577442; called by muse, mutect2, varscan2
- ABCC1 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1343930472; called by muse, mutect2, varscan2
- ABCC11 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as rs148400454; called by mutect2, varscan2
- ABCC12 | c.3745G>T p.E1249* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | catalogued as COSV60919158; called by muse, mutect2, varscan2
- ABCC12 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1216969755; called by muse, mutect2, varscan2
- ABCC12 | c.808T>C p.Y270H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60913257; called by muse, mutect2, varscan2
- ABCC12 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1287133996; called by muse, mutect2, varscan2
- ABCC2 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1221051389; called by muse, varscan2
- ABCC2 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs754646220, COSV64985593; called by muse, mutect2, varscan2
- ABCC2 | c.4450G>A p.A1484T | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs1354984709; called by muse, varscan2
- ABCC3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs781282162; called by muse, varscan2
- ABCC3 | c.3199C>T p.R1067C | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766311637, COSV53318397; called by muse, varscan2
- ABCC3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779268222; called by muse, varscan2
- ABCC3 | c.3716C>A p.A1239D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs146589964, COSV53325556; called by muse, mutect2, varscan2
- ABCC3 | c.4088G>A p.R1363H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370830587; called by muse, varscan2
- ABCC3 | c.4405C>T p.R1469C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs757031551; called by mutect2, varscan2
- ABCC4 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 89/173 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1345176162, COSV65311190; called by muse, mutect2, varscan2
- ABCC4 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65311433; called by muse, mutect2, varscan2
- ABCC5 | c.2053C>A p.L685M | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657708; called by muse, mutect2, varscan2
- ABCC5 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs377218084; called by muse, mutect2, varscan2
- ABCC5 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as rs749531253; called by muse, varscan2
- ABCC8 | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs771882862, COSV100217251; called by mutect2, varscan2
- ABCC9 | c.3851G>A p.S1284N | Missense Mutation (SNP) | VAF 63/421 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.171); catalogued as COSV99687544; called by muse, mutect2, varscan2
- ABCC9 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs1200576081, COSV53962315; called by muse, mutect2, varscan2
- ABCD4 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs373322009; called by muse, mutect2, varscan2
- ABCD4 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs369446810; called by muse, mutect2, varscan2
- ABCF2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55182510; called by muse, mutect2, varscan2
- ABCG1 | c.275G>T p.W92L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV59202422; called by muse, mutect2, varscan2
- ABCG1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as rs772406417; called by muse, varscan2
- ABCG2 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs1456149948; called by muse, mutect2, varscan2
- ABCG4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1160569038; called by muse, mutect2, varscan2
- ABCG4 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs201193587, COSV56643434; called by muse, mutect2, varscan2
- ABCG4 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs1333180580; called by muse, varscan2
- ABHD1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99574367; called by muse, mutect2, varscan2
- ABHD1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs368049308; called by muse, mutect2, varscan2
- ABHD11 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as rs782403925; called by muse, mutect2, varscan2
- ABHD11 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as rs148776431, COSV99766610; called by muse, mutect2, varscan2
- ABHD13 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566381694, COSV101024054; called by muse, mutect2, varscan2
- ABHD4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs768046002; called by muse, mutect2, varscan2
- ABHD4 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs200393007, COSV99360651; called by muse, mutect2, varscan2
- ABLIM1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV99522862; called by muse, mutect2, varscan2
- ABLIM1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs1452294373, COSV99521529; called by muse, mutect2, varscan2
- ABR | c.2152G>A p.A718T (on ENST00000302538 / NM_021962.5; = p.A681T on NM_001092.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs376689300; called by muse, mutect2
- ABT1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782670086; called by muse, mutect2, varscan2
- ABTB1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs147002334, COSV51740117; called by muse, varscan2
- AC004593.2 | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs1475141234; called by muse, mutect2, varscan2
- AC004922.1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.711); catalogued as rs200959894; called by mutect2, varscan2
- AC005833.1 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 60/159 reads (38%) | catalogued as COSV52894357; called by muse, mutect2, varscan2
- AC006059.2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs753800919; called by muse, mutect2, varscan2
- AC011455.2 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1335920603; called by muse, mutect2, varscan2
- AC013489.1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51552426; called by muse, varscan2
- AC013489.1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1567056827; called by muse, varscan2
- AC018630.4 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV101114599; called by muse, mutect2, varscan2
- AC097637.1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1162856520, COSV59726161; called by muse, mutect2, varscan2
- AC100868.1 | c.1640G>A p.R547K | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.688); catalogued as COSV51838201; called by muse, mutect2, varscan2
- AC100868.1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780723666, COSV99226895; called by muse, mutect2, varscan2
- AC131160.1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV57701376; called by muse, mutect2, varscan2
- AC131160.1 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs775771406; called by muse, mutect2, varscan2
- AC136428.1 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV71169148; called by muse, varscan2
- ACAA1 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1173037316; called by muse, mutect2, varscan2
- ACACA | c.5579G>A p.R1860Q | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435154885; called by muse, mutect2, varscan2
- ACACA | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as rs1258027850; called by muse, mutect2, varscan2
- ACACB | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268082822; called by muse, mutect2, varscan2
- ACAD10 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs764785788; called by muse, mutect2, varscan2
- ACAD10 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs765259177, COSV58153707; called by muse, mutect2, varscan2
- ACAD10 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs143673663; called by muse, mutect2, varscan2
- ACAD11 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as rs772764413, COSV99391621; called by muse, varscan2
- ACAD9 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs768894091; ClinVar: uncertain significance; called by mutect2, varscan2
- ACAD9 | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58307797; called by muse, mutect2, varscan2
- ACADL | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1425763481; called by muse, mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACADS | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs768292774, COSV54367981, COSV54370521; called by muse, mutect2, varscan2
- ACAN | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771842029, COSV61372675; called by muse, mutect2, varscan2
- ACAN | c.5369C>T p.S1790F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61359937; called by muse, mutect2, varscan2
- ACAP2 | c.1784C>A p.S595Y | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs779657743; called by muse, mutect2, varscan2
- ACAT1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1190813667, COSV99759442; called by muse, mutect2, varscan2
- ACBD3 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 54/157 reads (34%) | catalogued as COSV100830994, COSV100831108; called by muse, mutect2, varscan2
- ACBD5 | c.1348G>A p.A450T (on ENST00000375888 / NM_001352568.1; = p.A441T on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749212781, COSV101022429, COSV65521536; called by muse, mutect2, varscan2
- ACCS | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs373138553, COSV99772928; called by muse, mutect2, varscan2
- ACE | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569898686; called by muse, mutect2, varscan2
- ACE2 | c.2365G>T p.G789* | Nonsense Mutation (SNP) | VAF 99/137 reads (72%) | catalogued as COSV53023821; called by muse, mutect2, varscan2
- ACE2 | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 116/163 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV53024512; called by muse, mutect2, varscan2
- ACIN1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52972567; called by muse, mutect2, varscan2
- ACIN1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1381282818, COSV52975526; called by muse, varscan2
- ACKR1 | c.227G>T p.S76I | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100929684; called by muse, mutect2, varscan2
- ACLY | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs782746157, COSV61251431; called by muse, mutect2, varscan2
- ACLY | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs183942395; called by muse, mutect2, varscan2
- ACO1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.197); catalogued as rs774234584, COSV59377870; called by muse, mutect2, varscan2
- ACOT11 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs139052769; called by muse, varscan2
- ACOT12 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897277; called by muse, mutect2, varscan2
- ACOT4 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs780342168; called by muse, mutect2, varscan2
- ACOX3 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100712029; called by muse, mutect2, varscan2
- ACOXL | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490570; called by muse, mutect2, varscan2
- ACP4 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as rs143236952, COSV99567577; called by muse, mutect2, varscan2
- ACP5 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs1231519014, COSV54537393; called by muse, varscan2
- ACP7 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100488626; called by muse, mutect2, varscan2
- ACR | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272231856, COSV53361263; called by muse, mutect2, varscan2
- ACSBG1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs779018573, COSV51906355, COSV99357242; called by muse, mutect2, varscan2
- ACSBG1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs143166464; called by muse, mutect2, varscan2
- ACSBG1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs774511900, COSV51908268; called by mutect2, varscan2
- ACSBG1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771018417, COSV51908221; called by muse, mutect2, varscan2
- ACSF2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs556604565, COSV51972064; called by muse, mutect2, varscan2
- ACSF2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747334624, COSV51972091; called by muse, mutect2, varscan2
- ACSL1 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775495577; called by mutect2, varscan2
- ACSL3 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as rs746924445; called by muse, varscan2
- ACSL3 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756484315, COSV62483431; called by muse, mutect2, varscan2
- ACSL4 | c.398G>A p.R133H (on ENST00000340800 / NM_022977.2; = p.R92H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/130 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759239872, COSV100538274, COSV61613955; called by muse, varscan2
- ACSL5 | c.1058G>A p.R353Q (on ENST00000354273; = p.R409Q on NM_016234.3) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs759733603, COSV100634804; called by muse, mutect2, varscan2
- ACSL5 | c.1096G>A p.A366T (on ENST00000354273; = p.A422T on NM_016234.3) | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1240334731; called by muse, varscan2
- ACSL5 | c.1223G>A p.S408N (on ENST00000354273; = p.S464N on NM_016234.3) | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1300013785; called by muse, mutect2, varscan2
- ACSL5 | c.1619G>A p.R540H (on ENST00000354273; = p.R596H on NM_016234.3) | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201183294; called by muse, varscan2
- ACSL6 | c.691G>A p.E231K (on ENST00000379240; = p.E256K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV57297051; called by muse, mutect2, varscan2
- ACSM1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs746665178, COSV54637347; called by muse, mutect2, varscan2
- ACSM1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs779893812; called by muse, mutect2, varscan2
- ACSM2B | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 165/405 reads (41%) | catalogued as COSV61659342; called by muse, mutect2, varscan2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, varscan2
- ACSS2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 279/604 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780837244, COSV53624749; called by muse, varscan2
- ACSS2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs746077019, COSV53627180; called by muse, varscan2
- ACSS2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as rs1444654828; called by muse, mutect2, varscan2
- ACSS3 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV54090725; called by muse, mutect2, varscan2
- ACSS3 | c.1694G>T p.R565I | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54087208, COSV99699382; called by muse, varscan2
- ACTB | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV59320479; called by muse, mutect2, varscan2
- ACTBL2 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs1358229735, COSV101379422; called by muse, mutect2, varscan2
- ACTC1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51757594; called by muse, varscan2
- ACTG2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as rs758804225, COSV61828007; called by muse, mutect2, varscan2
- ACTL6B | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs570116007; called by mutect2, varscan2
- ACTL7A | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.528); catalogued as rs1378676527; called by muse, mutect2, varscan2
- ACTN1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1053046500, COSV99517258; called by muse, mutect2, varscan2
- ACTN2 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs554811924, COSV100856847, COSV63975796; called by muse, varscan2
- ACTN2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs730880041, COSV63973276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs767763639, COSV63971679; called by muse, mutect2, varscan2
- ACTN2 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as rs200854335, COSV100857079, COSV63975491, COSV63975814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN3 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs563563593; called by muse, varscan2
- ACTN4 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234222656, COSV53143783; called by muse, mutect2, varscan2
- ACTR1B | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1276575768, COSV56705001; called by muse, mutect2, varscan2
- ACTR2 | c.931C>A p.P311T | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV53202577; called by muse, mutect2, varscan2
- ACTR6 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764553782, COSV51840958, COSV51842988; called by muse, mutect2, varscan2
- ACTRT2 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV65758795; called by muse, mutect2
- ACTRT3 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57754590; called by muse, mutect2, varscan2
- ACVR1 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs776029462; called by muse, mutect2, varscan2
- ACVR1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs765195676; called by muse, mutect2, varscan2
- ACVR1C | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 47/184 reads (26%) | catalogued as rs368036845, COSV99695225; called by muse, mutect2, varscan2
- ACVR1C | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1336118698, COSV54643912; called by muse, varscan2
- ACVR2B | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs761653104, COSV61701328; called by mutect2, varscan2
- ACVR2B | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs747041699, COSV61701425; called by muse, mutect2, varscan2
- ADAM10 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs770353099; called by muse, mutect2, varscan2
- ADAM11 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1037353307, COSV52344942; called by muse, varscan2
- ADAM12 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64107225; called by muse, mutect2, varscan2
- ADAM12 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs145216562; called by muse, mutect2, varscan2
- ADAM12 | c.1892T>G p.L631R | Missense Mutation (SNP) | VAF 75/476 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64108948; called by muse, mutect2, varscan2
- ADAM15 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55127265, COSV55129509; called by muse, mutect2, varscan2
- ADAM15 | c.2015A>G p.H672R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1158151747; called by muse, mutect2, varscan2
- ADAM15 | c.2170C>T p.R724* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs142428973; called by muse, mutect2, varscan2
- ADAM17 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60401818; called by muse, varscan2
- ADAM18 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV99694768; called by muse, varscan2
- ADAM2 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1453580938; called by muse, mutect2, varscan2
- ADAM21 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99960610; called by muse, mutect2, varscan2
- ADAM22 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV55974095; called by muse, mutect2, varscan2
- ADAM22 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1349217218, COSV55985746; called by muse, varscan2
- ADAM23 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs751280747; called by muse, mutect2, varscan2
- ADAM28 | c.1944G>T p.E648D | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs758954662; called by muse, mutect2, varscan2
- ADAM29 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 66/123 reads (54%) | catalogued as COSV100822139, COSV63664593; called by muse, mutect2, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAM29 | c.2062T>C p.F688L | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753230754; called by muse, mutect2, varscan2
- ADAM30 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1200439340; called by muse, mutect2, varscan2
- ADAM7 | c.706-1G>T p.X236_splice | Splice Site (SNP) | VAF 19/107 reads (18%) | catalogued as COSV51537070; called by muse, mutect2, varscan2
- ADAM9 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs760058275, COSV65946602; called by muse, mutect2, varscan2
- ADAM9 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294592036; called by muse, mutect2, varscan2
- ADAMTS1 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs772156527, COSV53173123; called by muse, mutect2, varscan2
- ADAMTS12 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs377712954, COSV61260425; called by muse, varscan2
- ADAMTS13 | c.3272G>A p.G1091D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554795403, COSV52469827, COSV52470680; called by muse, mutect2, varscan2
- ADAMTS14 | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs748230861, COSV64599674; called by mutect2, varscan2
- ADAMTS14 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs757762785, COSV64600965; called by muse, varscan2
- ADAMTS14 | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs144598695; called by muse, varscan2
- ADAMTS15 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV100143470; called by muse, mutect2, varscan2
- ADAMTS16 | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs778918550, COSV56981665; called by muse, varscan2
- ADAMTS18 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs374647560; called by muse, mutect2, varscan2
- ADAMTS2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753810968, COSV51074569, COSV51083189; called by muse, varscan2
- ADAMTS2 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs763905470, COSV51083557; called by muse, varscan2
- ADAMTS20 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs779517298, COSV67135947; called by muse, mutect2, varscan2
- ADAMTS20 | c.2033C>A p.P678H | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101238986; called by muse, mutect2, varscan2
- ADAMTS20 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV67129951; called by muse, mutect2, varscan2
- ADAMTS3 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749717867, COSV54400766; called by muse, mutect2, varscan2
- ADAMTS5 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755967040, COSV53177017; called by muse, mutect2, varscan2
- ADAMTS5 | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs202109841, COSV53185636; called by muse, mutect2, varscan2
- ADAMTS6 | c.3001C>T p.P1001S | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV58684413; called by muse, mutect2, varscan2
- ADAMTS6 | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs775821305; called by muse, mutect2, varscan2
- ADAMTS9 | c.4472G>A p.R1491K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADAMTS9 | c.1343A>C p.N448T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.232); catalogued as COSV99900070; called by muse, varscan2
- ADAMTSL1 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.219); catalogued as rs752262465; called by muse, varscan2
- ADAMTSL1 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs3004643, COSV65889692; called by muse, mutect2, varscan2
- ADAMTSL2 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs780731869, COSV63206170; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTSL3 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs775863035; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4183G>A p.V1395I | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs762478236, COSV99721400; called by muse, mutect2, varscan2
- ADAMTSL4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99071646; called by muse, mutect2
- ADAP2 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144736072; called by muse, varscan2
- ADARB1 | c.1561C>T p.R521W (on ENST00000360697 / NM_001346687.2; = p.R481W on NM_001112.4) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183960739; called by muse, varscan2
- ADARB1 | c.1601G>A p.R534H (on ENST00000360697 / NM_001346687.2; = p.R494H on NM_001112.4) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201477864; called by muse, varscan2
- ADARB1 | c.1885G>A p.A629T (on ENST00000360697 / NM_001346687.2; = p.A589T on NM_001112.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs766126367; called by mutect2, varscan2
- ADAT1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as rs778703472, COSV57187830; called by muse, mutect2, varscan2
- ADCK1 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs766265393, COSV53079027; called by muse, mutect2, varscan2
- ADCK1 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs142511548; called by muse, mutect2, varscan2
- ADCK1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751408118, COSV104380131, COSV53080954; called by muse, varscan2
- ADCK1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs749350658, COSV53079548; called by muse, varscan2
- ADCY10 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as rs779693508; called by muse, mutect2, varscan2
- ADCY10 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.478); catalogued as rs774828588, COSV63240542; called by muse, varscan2
- ADCY3 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs772276162, COSV53168509; called by mutect2, varscan2
- ADCY3 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs748716285; called by muse, varscan2
- ADCY4 | c.1850G>T p.S617I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100156227; called by muse, varscan2
- ADCY4 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765076936; called by mutect2, varscan2
- ADCY8 | c.2412C>T p.I804= | Splice Region (SNP) | VAF 19/93 reads (20%) | catalogued as rs1433379964, COSV99036571; called by muse, mutect2, varscan2
- ADCY9 | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs545959256; called by muse, mutect2, varscan2
- ADCY9 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as rs545216961, COSV104396401; called by muse, varscan2
- ADCY9 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1160205554; called by muse, mutect2, varscan2
- ADCY9 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as rs779690355, COSV53577400; called by muse, mutect2, varscan2
- ADCY9 | c.709G>A p.V237I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as rs766756605, COSV53575298; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV100416046; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs763855179; called by muse, mutect2, varscan2
- ADD2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781842295, COSV52458987; called by muse, varscan2
- ADD2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104389111; called by muse, mutect2
- ADD3 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1325961652; called by muse, mutect2, varscan2
- ADGRA3 | c.3940T>A p.L1314I | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV51559992; called by muse, varscan2
- ADGRA3 | c.3881G>T p.S1294I | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51562545, COSV99292839; called by muse, varscan2
- ADGRA3 | c.3653C>T p.S1218L | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs759989405; called by muse, mutect2, varscan2
- ADGRA3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 99/175 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201944807; called by muse, mutect2, varscan2
- ADGRA3 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as rs144734405; called by muse, mutect2, varscan2
- ADGRB3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs779693752; called by muse, mutect2, varscan2
- ADGRB3 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs376079687; called by muse, mutect2, varscan2
- ADGRB3 | c.3915A>C p.E1305D | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.978); catalogued as COSV53262770; called by muse, mutect2, varscan2
- ADGRD1 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as rs766201065; called by muse, mutect2, varscan2
- ADGRE1 | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 153/314 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99165212; called by muse, mutect2, varscan2
- ADGRE5 | c.2102C>T p.T701I (on ENST00000242786 / NM_078481.4; = p.T608I on NM_001784.5) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs751555379; called by muse, mutect2, varscan2
- ADGRF1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs548677249; called by muse, mutect2, varscan2
- ADGRF3 | c.3109C>T p.R1037C (on ENST00000311519 / NM_001145168.1; = p.R838C on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1278140623, COSV61051496; called by muse, varscan2
- ADGRF3 | c.1978C>T p.R660* (on ENST00000311519 / NM_001145168.1; = p.R461* on NM_153835.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs116734873; called by muse, mutect2, varscan2
- ADGRF3 | c.1862C>T p.A621V (on ENST00000311519 / NM_001145168.1; = p.A422V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.166); catalogued as rs1284332901; called by muse, mutect2, varscan2
- ADGRF4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs755972498; called by muse, mutect2, varscan2
- ADGRG1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs587783659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRG4 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 208/555 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs759179086; called by muse, mutect2, varscan2
- ADGRG4 | c.8248G>A p.G2750R | Missense Mutation (SNP) | VAF 72/95 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766084197; called by muse, mutect2, varscan2
- ADGRG5 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1228478117, COSV61082957; called by muse, mutect2, varscan2
- ADGRG6 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 72/126 reads (57%) | catalogued as rs749312742, COSV51594514; called by muse, mutect2, varscan2
- ADGRG7 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs777345638; called by muse, mutect2, varscan2
- ADGRL1 | c.3674G>A p.R1225Q (on ENST00000340736 / NM_001008701.3; = p.R1220Q on NM_014921.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as rs566513234; called by muse, mutect2, varscan2
- ADGRL2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780914901; called by muse, mutect2, varscan2
- ADGRL2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54677127; called by muse, mutect2, varscan2
- ADGRL3 | c.1387G>A p.D463N (on ENST00000506720 / NM_001322402.2; = p.D395N on NM_015236.6) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs543714483; called by muse, mutect2, varscan2
- ADGRL3 | c.1627G>A p.E543K (on ENST00000506720 / NM_001322402.2; = p.E475K on NM_015236.6) | Missense Mutation (SNP) | VAF 145/291 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs770294775; called by muse, mutect2, varscan2
- ADGRV1 | c.10711G>A p.A3571T | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67993920; called by muse, mutect2, varscan2
- ADGRV1 | c.14303C>T p.S4768L | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs200130204, COSV67984486; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.16775C>A p.P5592H | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67996239; called by muse, mutect2, varscan2
- ADGRV1 | c.18548C>T p.T6183M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201790936; called by mutect2, varscan2
- ADH5 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs773778500, COSV56447875, COSV99596150; called by muse, mutect2, varscan2
- ADH5 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs761349329, COSV56447491; called by muse, mutect2, varscan2
- ADH6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756863693, COSV52955529; called by muse, mutect2, varscan2
- ADHFE1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 84/309 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs368995778; called by muse, mutect2, varscan2
- ADHFE1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs148191690; called by muse, mutect2, varscan2
- ADNP | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773922977, COSV100823790; called by muse, mutect2, varscan2
- ADNP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV62424517; called by muse, varscan2
- ADORA2A | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs773766284; called by muse, mutect2, varscan2
- ADRA1A | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938487720, COSV52362588; called by muse, varscan2
- ADRA1B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs1330843392, COSV100140049; called by muse, mutect2, varscan2
- ADRA1B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757479764, COSV60704032; called by muse, mutect2, varscan2
- ADRA1B | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.065); catalogued as rs751740593, COSV60700411; called by muse, mutect2, varscan2
- ADRA2A | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs764891418, COSV54527528; called by muse, mutect2, varscan2
- ADRA2B | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs1377964689; called by muse, mutect2, varscan2
- ADRB2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV60005755; called by muse, mutect2, varscan2
- ADRB2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs377115303, COSV60005825; called by muse, mutect2, varscan2
- ADSL | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs775298300, COSV53409842; called by muse, mutect2, varscan2
- AEBP1 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV56261148; called by muse, mutect2, varscan2
- AEBP2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs754732926, COSV99857986; called by muse, mutect2, varscan2
- AEN | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756247681, COSV60428818; called by mutect2, varscan2
- AEN | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs978995127; called by muse, mutect2
- AF196969.1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as rs147961959; called by muse, mutect2, varscan2
- AFAP1L2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145401018; called by muse, mutect2, varscan2
- AFF1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 245/474 reads (52%) | catalogued as rs780728413, COSV57121784; called by muse, mutect2, varscan2
- AFF1 | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749334094; called by muse, mutect2, varscan2
- AFF2 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.175); catalogued as rs1264155489; called by muse, mutect2, varscan2
- AFF3 | c.3360G>A p.M1120I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1418264157; called by muse, mutect2, varscan2
- AFF3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57855949, COSV57878534; called by muse, mutect2, varscan2
- AFF3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1398330526, COSV100420315; called by muse, varscan2
- AFF4 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as COSV54791578; called by muse, mutect2, varscan2
- AFF4 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as rs759650836; called by muse, mutect2, varscan2
- AFG3L2 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs374353312; called by muse, mutect2
- AFMID | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs770780731, COSV59976181; called by muse, mutect2, varscan2
- AFTPH | c.2377A>G p.T793A | Missense Mutation (SNP) | VAF 117/663 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1365246832; called by muse, mutect2, varscan2
- AGA | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572348048, COSV99219586; called by muse, mutect2
- AGAP1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs757882352; called by muse, mutect2, varscan2
- AGAP1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs573706698, COSV58323488; called by muse, mutect2, varscan2
- AGAP2 | c.1718A>G p.Q573R (on ENST00000547588 / NM_001122772.2; = p.Q237R on NM_014770.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1210793466; called by muse, mutect2
- AGBL2 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs900125924; called by muse, mutect2, varscan2
- AGBL5 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.999); catalogued as rs368224692, COSV64079938; called by muse, mutect2, varscan2
- AGGF1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs368093330; called by muse, mutect2, varscan2
- AGGF1 | c.1316A>T p.E439V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs769516475; called by muse, mutect2, varscan2
- AGL | c.4215A>C p.E1405D | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs943975004; called by muse, varscan2
- AGMO | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61106127; called by muse, varscan2
- AGO1 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157651125; called by muse, varscan2
- AGO2 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55045124; called by muse, mutect2, varscan2
- AGO3 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as rs1244575080, COSV55790721, COSV55792811; called by muse, mutect2, varscan2
- AGO3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs765473330; called by muse, varscan2
- AGO4 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.764); catalogued as COSV100942986; called by muse, mutect2, varscan2
- AGPAT4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1006582804; called by muse, mutect2, varscan2
- AGPAT4 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57251718; called by muse, mutect2, varscan2
- AGPAT5 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs756652472, COSV53449451; called by muse, varscan2
- AGPAT5 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs570636724; called by muse, varscan2
- AGPS | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 78/205 reads (38%) | catalogued as rs1345538545, COSV51568402; called by muse, mutect2, varscan2
- AGXT2 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.834); catalogued as COSV51492092; called by muse, mutect2
- AHCTF1 | c.3569C>T p.S1190L (on ENST00000366508; = p.S1164L on NM_015446.5) | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs377375258; called by muse, mutect2, varscan2
- AHCTF1 | c.1846C>T p.R616C (on ENST00000366508; = p.R590C on NM_015446.5) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs770031454, COSV58253892; called by mutect2, varscan2
- AHCTF1 | c.358G>T p.E120* (on ENST00000366508; = p.E94* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 48/138 reads (35%) | catalogued as COSV58247935; called by muse, varscan2
- AHCTF1 | c.208C>T p.R70C (on ENST00000366508; = p.R44C on NM_015446.5) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1307075702, COSV58253990; called by muse, mutect2, varscan2
- AHCYL1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as rs1259490926, COSV63208413; called by muse, mutect2, varscan2
- AHCYL1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs750092870, COSV63208745; called by muse, mutect2, varscan2
- AHDC1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55936756; called by muse, mutect2, varscan2
- AHI1 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769705227, COSV55637817; called by muse, mutect2, varscan2
- AHI1 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs373384543; called by muse, mutect2, varscan2
- AHI1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs553366477; called by muse, mutect2, varscan2
- AHNAK | c.17129C>T p.S5710F | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99946885; called by muse, mutect2, varscan2
- AHNAK | c.16246C>T p.P5416S | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1318050826, COSV57234361; called by muse, mutect2, varscan2
- AHNAK | c.4935G>T p.E1645D | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs1220259247, COSV99945636; called by muse, mutect2, varscan2
- AHNAK | c.4337T>C p.I1446T | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as rs954612994; called by muse, mutect2, varscan2
- AHNAK | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs763485398, COSV57217512; called by muse, mutect2, varscan2
- AHNAK2 | c.17326G>A p.E5776K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773270822; called by muse, mutect2, varscan2
- AHNAK2 | c.14047G>A p.D4683N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs375463111; called by muse, mutect2, varscan2
- AHNAK2 | c.13826G>A p.R4609Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs758388095; called by muse, mutect2, varscan2
- AHNAK2 | c.11398G>T p.D3800Y | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV60907334; called by muse, varscan2
- AHNAK2 | c.9301G>A p.D3101N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); catalogued as rs775880388; called by muse, mutect2, varscan2
- AHNAK2 | c.5933A>G p.D1978G | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV60911587; called by muse, varscan2
- AICDA | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs747680644, COSV57565731; ClinVar: uncertain significance; called by muse, varscan2
- AIG1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as rs549007002; called by muse, mutect2, varscan2
- AIPL1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV51506891, COSV51506998; called by mutect2, varscan2
- AIPL1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779454542, COSV51507918; called by muse, mutect2, varscan2
- AK5 | c.1435G>T p.D479Y (on ENST00000354567 / NM_174858.3; = p.D453Y on NM_012093.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1349937397; called by muse, mutect2
- AK7 | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs753576637; called by muse, mutect2, varscan2
- AK7 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767851012, COSV50879282; called by muse, mutect2, varscan2
- AK9 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767239755, COSV58141801; called by muse, mutect2, varscan2
- AKAP1 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV61806342; called by muse, mutect2, varscan2
- AKAP11 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as COSV50298571; called by muse, mutect2, varscan2
- AKAP11 | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 106/168 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs150888197; called by muse, mutect2, varscan2
- AKAP11 | c.5643G>A p.M1881I | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1410279062; called by muse, mutect2, varscan2
- AKAP12 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs746212006, COSV53577292; called by muse, mutect2, varscan2
- AKAP13 | c.6599G>A p.R2200H (on ENST00000394518 / NM_007200.5; = p.R2204H on NM_006738.6) | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs531745352, COSV63449825; called by muse, varscan2
- AKAP3 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57420978; called by muse, mutect2, varscan2
- AKAP3 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1189247607; called by muse, mutect2, varscan2
- AKAP5 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs758946070, COSV57742121; called by muse, mutect2, varscan2
- AKAP6 | c.3372G>T p.K1124N | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99803394; called by muse, mutect2, varscan2
- AKAP6 | c.5627G>A p.R1876H | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs201188217, COSV55208303; called by muse, mutect2, varscan2
- AKAP8L | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV68472851; called by muse, mutect2
- AKAP9 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs864622705, COSV100662522, COSV62344491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.5794C>T p.R1932* (on ENST00000359028; = p.R1900* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs978219635, COSV62354761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.10375C>T p.R3459* (on ENST00000359028; = p.R3435* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/192 reads (21%) | catalogued as COSV100662600; called by muse, mutect2, varscan2
- AKAP9 | c.11056C>T p.L3686F (on ENST00000359028; = p.L3662F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430462964, COSV100662528; called by muse, mutect2, varscan2
- AKAP9 | c.11368C>T p.R3790W (on ENST00000359028; = p.R3766W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774732981, COSV100662142; called by muse, mutect2, varscan2
- AKNA | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs149421926; called by muse, mutect2, varscan2
- AKNAD1 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 115/215 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0.033); catalogued as rs756248528, COSV64172333; called by muse, mutect2, varscan2
- AKR1B1 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs371173126; called by muse, mutect2, varscan2
- AKR1B15 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71152541; called by muse, mutect2, varscan2
- AKR1C3 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1351026866; called by muse, varscan2
- AKR1C3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs782156465, COSV65910858; called by muse, mutect2, varscan2
- AKR1D1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs116226492, COSV54338706; called by muse, mutect2, varscan2
- AKR7A2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs146046785, COSV52515657; called by mutect2, varscan2
- AKR7L | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1399307457; called by muse, mutect2, varscan2
- AKT2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs781260194; called by muse, mutect2, varscan2
- AKT3 | c.1252-1G>A p.X418_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | catalogued as COSV55606907; called by muse, mutect2
- AL136295.1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs772121073; called by muse, varscan2
- AL136295.1 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55779473; called by muse, varscan2
- AL441992.2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766480924, COSV56916082; called by muse, mutect2, varscan2
- AL592490.1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs147863563; called by muse, mutect2, varscan2
- AL645922.1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.77); catalogued as rs1277611780, COSV54962135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL645922.1 | c.2045A>G p.Q682R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as rs769720437; called by muse, varscan2
- AL645922.1 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs1337987193; called by muse, varscan2
- ALAS1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs761283191, COSV59627723; called by muse, mutect2, varscan2
- ALAS1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140582251, COSV100050354; called by muse, mutect2, varscan2
- ALAS1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs780609581; called by muse, varscan2
- ALAS2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); catalogued as rs202150943, COSV58192002; called by muse, varscan2
- ALCAM | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 140/357 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs374882622; called by muse, mutect2, varscan2
- ALDH18A1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs773903524, COSV100973155; called by muse, mutect2, varscan2
- ALDH1L2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs763371443, COSV51559408; called by muse, varscan2
- ALDH2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs534531260, COSV55666053; called by muse, mutect2, varscan2
- ALDH3A1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs774582773, COSV56735365; called by muse, mutect2, varscan2
- ALDH3B1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs865916355, COSV50287861, COSV50291066; called by muse, varscan2
- ALDH3B2 | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757404973; called by muse, varscan2
- ALDH5A1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773814880, COSV62373402, COSV62374578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH5A1 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs1286399007; called by muse, mutect2, varscan2
- ALDH5A1 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs768957232, COSV62372957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH6A1 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV63246311; called by muse, mutect2, varscan2
- ALDH8A1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774809603, COSV55640438; called by muse, mutect2, varscan2
- ALDH9A1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV61339529; called by muse, mutect2, varscan2
- ALDH9A1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760770069, COSV61341033; called by muse, varscan2
- ALDOC | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1278155939; called by muse, mutect2, varscan2
- ALG12 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | PolyPhen benign (0.003); catalogued as COSV58208325; called by muse, varscan2
- ALG2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53059154; called by muse, varscan2
- ALG2 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV99445405; called by muse, mutect2, varscan2
- ALG3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs763104840; called by muse, varscan2
- ALG5 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); catalogued as rs1335305528; called by muse, mutect2, varscan2
- ALG9 | c.1585G>A p.D529N (on ENST00000614444 / NM_001352418.1; = p.D536N on NM_024740.2) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.104); catalogued as COSV67645107; called by muse, mutect2, varscan2
- ALK | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.565); catalogued as rs150344432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV66591309; called by muse, mutect2, varscan2
- ALK | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99072913; called by muse, mutect2, varscan2
- ALK | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66588492; called by muse, mutect2, varscan2
- ALKBH3 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs542847003; called by muse, mutect2, varscan2
- ALKBH3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs745683816; called by muse, mutect2, varscan2
- ALKBH6 | c.203G>A p.R68Q (on ENST00000252984 / NM_001297701.2; = p.R96Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1274474050, COSV99431054, COSV99431236; called by muse, mutect2
- ALMS1 | c.12040C>T p.R4014W | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs543346172; called by muse, mutect2
- ALMS1 | c.12256C>T p.R4086W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779618627, COSV52514702; called by muse, mutect2, varscan2
- ALOX12 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs768496365, COSV52348362; called by muse, varscan2
- ALOX15B | c.368-1G>T p.X123_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV66479495; called by muse, mutect2, varscan2
- ALOX15B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs375708086, COSV66479103; called by muse, mutect2, varscan2
- ALOX15B | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749876352, COSV101205546; called by muse, varscan2
- ALOX5 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771622355, COSV65550810; called by muse, mutect2, varscan2
- ALOX5 | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV65553424; called by muse, varscan2
- ALOX5AP | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs770152662; called by muse, mutect2, varscan2
- ALPK2 | c.5704G>T p.E1902* | Nonsense Mutation (SNP) | VAF 73/140 reads (52%) | catalogued as COSV64490749; called by muse, mutect2, varscan2
- ALPK2 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs1274100693; called by muse, mutect2
- ALPK2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184186856, COSV100864540; called by muse, mutect2, varscan2
- ALPK3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1172324544, COSV51936070; called by muse, mutect2, varscan2
- ALPK3 | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374420068; called by muse, mutect2, varscan2
- ALPK3 | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs371508067; called by mutect2, varscan2
- ALPL | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.478); catalogued as rs1436960562, CM121128; called by muse, mutect2, varscan2
- ALS2 | c.3026G>A p.R1009K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51892768, COSV51894007; called by muse, mutect2, varscan2
- ALS2 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.829); catalogued as rs1559079541; called by muse, mutect2, varscan2
- ALX1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as rs1454076521, COSV100374319, COSV57492423; called by muse, mutect2, varscan2
- ALX1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 54/87 reads (62%) | catalogued as rs150997122, COSV57492012; called by muse, mutect2, varscan2
- AMBP | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs780641166, COSV99469380; called by muse, varscan2
- AMBRA1 | c.2887C>T p.R963* (on ENST00000458649 / NM_001367468.1; = p.R873* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs764989472, COSV54050338; called by mutect2, varscan2
- AMBRA1 | c.1706G>A p.R569H (on ENST00000458649 / NM_001367468.1; = p.R479H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768009155; called by muse, mutect2, varscan2
- AMBRA1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 83/511 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775568948; called by muse, mutect2, varscan2
- AMD1 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370327573, COSV64387377; called by muse, varscan2
- AMER3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs147594621; called by muse, mutect2, varscan2
- AMER3 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as rs1055694945; called by muse, mutect2, varscan2
- AMFR | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs756216374, COSV51920040; called by muse, mutect2, varscan2
- AMIGO1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs751993737; called by muse, mutect2, varscan2
- AMIGO1 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.239); catalogued as rs1181277113; called by muse, mutect2, varscan2
- AMIGO3 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751879667, COSV57540497; called by mutect2, varscan2
- AMMECR1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs1442755336; called by muse, varscan2
- AMMECR1L | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55760482; called by muse, mutect2, varscan2
- AMN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs889986563, COSV55671992; called by muse, mutect2, varscan2
- AMN1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs772678124, COSV99861678; called by muse, mutect2, varscan2
- AMOT | c.1717G>A p.E573K (on ENST00000371959 / NM_001113490.1; = p.E164K on NM_133265.3) | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs767625475, COSV59060609; called by muse, mutect2, varscan2
- AMOTL2 | c.1154G>T p.R385M | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs949173320; called by muse, mutect2, varscan2
- AMPD1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs139512772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD3 | c.992G>A p.R331H (on ENST00000396553 / NM_001025389.2; = p.R340H on NM_000480.3) | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs1425942523, COSV67331273; called by muse, mutect2, varscan2
- AMPH | c.1231T>G p.L411V | Missense Mutation (SNP) | VAF 152/362 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.231); catalogued as COSV57752010; called by muse, mutect2, varscan2
- AMPH | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1032416581, COSV100342680, COSV100343083; called by muse, mutect2, varscan2
- AMPH | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272402161, COSV57740359; called by muse, mutect2, varscan2
- AMY2B | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 70/294 reads (24%) | catalogued as rs770249517, COSV63714026; called by muse, varscan2
- AMY2B | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 263/918 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767168411, COSV100796287; called by muse, mutect2, varscan2
- AMZ2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63082848; called by muse, varscan2
- ANAPC1 | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1322440253; called by muse, mutect2, varscan2
- ANAPC1 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 53/127 reads (42%) | catalogued as rs1437191682; called by muse, mutect2, varscan2
- ANAPC1 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1435638489, COSV61977500; called by muse, mutect2, varscan2
- ANAPC1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs368190060; called by muse, mutect2, varscan2
- ANAPC10 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58739104; called by muse, mutect2, varscan2
- ANAPC5 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.711); catalogued as COSV55842788; called by muse, mutect2, varscan2
- ANAPC5 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs782375551; called by muse, mutect2, varscan2
- ANG | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as rs954462835, COSV100390911; called by muse, varscan2
- ANGEL1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs375071846; called by muse, mutect2, varscan2
- ANGEL2 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs150486074; called by muse, mutect2, varscan2
- ANGPT1 | c.1186A>C p.N396H | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1431512891; called by muse, mutect2, varscan2
- ANGPTL1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs143247341, COSV52368712; called by muse, mutect2, varscan2
- ANGPTL2 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200073434, COSV99400593; called by muse, mutect2, varscan2
- ANK1 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.163); catalogued as rs375228300, COSV99227674; called by muse, mutect2, varscan2
- ANK1 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763961763, COSV55891497, COSV99223905; called by muse, mutect2, varscan2
- ANK1 | c.1541G>A p.G514D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs747138779; called by muse, varscan2
- ANK2 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52162669; called by muse, varscan2
- ANK2 | c.4843C>A p.P1615T | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.547); catalogued as COSV99998816; called by muse, mutect2, varscan2
- ANK2 | c.9487G>A p.A3163T | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as COSV52153114; called by muse, mutect2, varscan2
- ANK3 | c.4631C>T p.S1544L | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as rs754585055, COSV55042994; called by muse, varscan2
- ANK3 | c.3662C>T p.P1221L (on ENST00000280772 / NM_001320874.2; = p.P355L on NM_001149.3) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs899181117; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 60/152 reads (39%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANK3 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377696913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748593236, COSV55046495; called by muse, mutect2, varscan2
- ANKAR | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs148013275; called by muse, mutect2, varscan2
- ANKEF1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757587718, COSV65693267; called by muse, mutect2, varscan2
- ANKEF1 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs138316568; called by muse, mutect2, varscan2
- ANKEF1 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 61/106 reads (58%) | catalogued as COSV65692051; called by muse, mutect2, varscan2
- ANKFN1 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV100593546; called by muse, varscan2
- ANKFY1 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs781312308; called by muse, mutect2, varscan2
- ANKH | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.031); catalogued as rs753303788; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5554C>T p.P1852S | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV51849949; called by muse, mutect2, varscan2
- ANKIB1 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs373686304; called by muse, mutect2, varscan2
- ANKIB1 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99728560; called by muse, mutect2, varscan2
- ANKIB1 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56062145; called by muse, mutect2, varscan2
- ANKLE2 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201586661, COSV61709281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKLE2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs889582581, COSV61711796; called by muse, mutect2
- ANKMY1 | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748134301; called by muse, mutect2, varscan2
- ANKMY2 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs1562774793; called by muse, mutect2, varscan2
- ANKRA2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as rs778296728; called by muse, mutect2, varscan2
- ANKRD1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.384); catalogued as rs1293523344, COSV65467209; called by muse, mutect2, varscan2
- ANKRD10 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs761519788; called by muse, mutect2, varscan2
- ANKRD11 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1406602469, COSV99969632; called by muse, mutect2, varscan2
- ANKRD11 | c.3233C>T p.A1078V | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs753662123, COSV56360062; called by muse, mutect2, varscan2
- ANKRD11 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs370690185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.2992T>A p.L998I | Missense Mutation (SNP) | VAF 118/472 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs1331100745; called by muse, varscan2
- ANKRD12 | c.4511C>T p.S1504L | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as rs779121149; called by muse, mutect2, varscan2
- ANKRD13A | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs748435968, COSV55677971; called by muse, mutect2, varscan2
- ANKRD16 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs368461065; called by muse, mutect2, varscan2
- ANKRD17 | c.7319C>T p.T2440M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs770029425, COSV58230227; called by muse, mutect2, varscan2
- ANKRD2 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761713500; called by muse, varscan2
- ANKRD22 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV64235850; called by muse, varscan2
- ANKRD24 | c.3112C>T p.R1038C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs373558892; called by muse, varscan2
- ANKRD28 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs566591150; called by muse, mutect2, varscan2
- ANKRD30A | c.703G>T p.D235Y (on ENST00000611781; = p.D179Y on NM_052997.2) | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100654636; called by muse, mutect2, varscan2
- ANKRD30A | c.2034G>T p.K678N (on ENST00000611781; = p.K622N on NM_052997.2) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV64610428, COSV64624442; called by muse, mutect2, varscan2
- ANKRD30A | c.3550G>A p.E1184K (on ENST00000611781; = p.E1128K on NM_052997.2) | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV64610842; called by muse, mutect2, varscan2
- ANKRD34A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60161440; called by muse, mutect2, varscan2
- ANKRD35 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs782145699, COSV62910724; called by muse, mutect2, varscan2
- ANKRD35 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs781812215; called by muse, mutect2, varscan2
- ANKRD40 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs763470156, COSV53333125; called by muse, varscan2
- ANKRD42 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99473607; called by muse, mutect2, varscan2
- ANKRD50 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1225400170, COSV72385307; called by muse, mutect2, varscan2
- ANKRD52 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1294885547; called by muse, mutect2, varscan2
- ANKRD6 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as rs369619069, COSV60237478; called by muse, mutect2, varscan2
- ANKRD6 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60235608; called by muse, mutect2, varscan2
- ANKS1B | c.2614C>A p.L872I (on ENST00000547776 / NM_152788.4; = p.L98I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.723); catalogued as COSV60357455; called by muse, mutect2, varscan2
- ANKZF1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371915106; called by muse, mutect2, varscan2
- ANLN | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576328951, COSV56074757, COSV56077152; called by muse, mutect2, varscan2
- ANLN | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs766697251, COSV56075297; called by muse, mutect2, varscan2
- ANO2 | c.2701G>A p.A901T (on ENST00000356134 / NM_001278597.3; = p.A905T on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs897115855, COSV59046699; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 164/390 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, varscan2
- ANO4 | c.2576G>A p.R859Q (on ENST00000392977 / NM_001286615.2; = p.R824Q on NM_178826.4) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770666618; called by muse, varscan2
- ANO5 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as rs746511547, COSV61084743; called by muse, mutect2, varscan2
- ANO9 | c.1983G>T p.K661N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV100229968; called by muse, mutect2, varscan2
- ANO9 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs757068080, COSV100240724; called by muse, varscan2
- ANOS1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs754571346, COSV52921277; called by muse, varscan2
- ANP32D | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 84/491 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs777687157, COSV56980408; called by muse, mutect2, varscan2
- ANXA10 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | catalogued as rs1192134579, COSV100829098; called by muse, mutect2, varscan2
- ANXA13 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs112185912, COSV99146133; called by muse, mutect2, varscan2
- ANXA3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.298); catalogued as rs1359809932; called by muse, varscan2
- ANXA3 | c.915G>A p.S305= | Splice Region (SNP) | VAF 32/107 reads (30%) | catalogued as rs746463276; called by muse, mutect2, varscan2
- ANXA4 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778785400; called by muse, mutect2, varscan2
- ANXA6 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs540689618; called by muse, mutect2, varscan2
- ANXA7 | c.644G>A p.R215H (on ENST00000372919 / NM_001320880.2; = p.R193H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs770294831, COSV65823486; called by muse, mutect2, varscan2
- AOC1 | c.1667A>G p.Q556R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV62868092; called by muse, mutect2, varscan2
- AOC1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766897897; called by mutect2, varscan2
- AOC3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750442526; called by mutect2, varscan2
- AOC3 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757517219; called by muse, mutect2, varscan2
- AOPEP | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs778059579, COSV52924860; called by muse, mutect2, varscan2
- AOX1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs368293055, COSV65981353; called by muse, mutect2, varscan2
- AOX1 | c.3868G>T p.A1290S | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV53497402; called by muse, mutect2, varscan2
- AP002512.3 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 64/117 reads (55%) | catalogued as rs749473920, COSV54405969; called by muse, mutect2, varscan2
- AP002748.5 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1037134217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs148914816; called by muse, varscan2
- AP1G1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs376889684, COSV100250587; called by muse, varscan2
- AP1G2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs772550436, COSV58111683; called by muse, mutect2, varscan2
- AP1M1 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs151315587; called by muse, mutect2, varscan2
- AP2B1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757180229, COSV99251845; called by muse, varscan2
- AP2B1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs1249030356; called by muse, varscan2
- AP2B1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52003019; called by muse, mutect2, varscan2
- AP2M1 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV53050200; called by mutect2, varscan2
- AP2M1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV53047642; called by muse, varscan2
- AP2S1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1012111005; called by muse, mutect2, varscan2
- AP3B1 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs769458241; called by muse, mutect2, varscan2
- AP3B2 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55612744; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by muse, mutect2, varscan2
- AP4B1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528147130, COSV56725492; called by muse, mutect2, varscan2
30,548 further variants in this file (22,376 protein-altering or splice-affecting, 7,558 silent, 614 other) are not listed here.
